Gene-level copy-number profile of specimen HCM-BROD-0695-C71-85R from HCMI case HCM-BROD-0695-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.3 years (21,646 days).
Specimen HCM-BROD-0695-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eac28002-4939-4c96-a765-af3d493fac86.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0695-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/4beee499-9226-417f-adca-4887b559ea53

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 74; copy number 2: 5,921; copy number 3: 2,754; copy number 4: 44,848; copy number 5: 288; copy number 6: 5,004; copy number 8: 2; copy number 9: 1; copy number 44: 17.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,330,670–55,433,742, 17 genes, copy number 44: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr7:123,749,068–123,751,166, 1 gene, copy number 9: WASL-DT.

Autosomal genes at a single copy (total copy number 1): 66. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
